Surgical pathology report (de-identified scan), TCGA case TCGA-90-7767, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-90-7767-01A (Primary Tumor).

[page 1 of 3]
Final Pathologic Diagnosis:

- A. Lung, right, resection:
Poorly differentiated squamous cell carcinoma.
All margins negative for neoplasm.
Carcinoma involving 3 out of 11 lymph nodes (3/11)
- B. Lymph node, level 7 subcarinal, excision:
One lymph node negative for neoplasm (0/1).
- C. Lymph nodes, upper paratracheal, excision:
Three lymph nodes negative for neoplasm (0/3).
- D. Lymph nodes, lower paratracheal, excision:
Thirteen lymph nodes negative for neoplasm (0/13).
- E. Lymph nodes, level 10, excision:
Three lymph nodes negative for neoplasm (0/3).
- F. Bronchial margin, excision:
Negative for malignancy.
Frozen section diagnosis confirmed.

Lung resection:

Specimen: Lung
Procedure: Pneumonectomy
Specimen laterality: Right
Tumor site: Upper lobe
Specimen integrity: Intact
Tumor size: 6 cm (greatest dimension)
Tumor focality: Unifocal
Tumor histologic type: Squamous carcinoma
Tumor grade: Poorly differentiated
Visceral pleura invasion: None
Tumor extension: Not applicable

Margins:

Bronchial margin: Uninvolved by invasive carcinoma
Vascular margin: Uninvolved by invasive carcinoma
Parietal pleural margin: Not applicable
Chest wall margin: Not applicable
Other attached tissue margin: Not applicable
If all margins uninvolved by invasive carcinoma:
Distance of invasive carcinoma from closest margin: 9 mm

Specify margin: Parenchymal
Treatment effect: Not applicable
Lymph-vascular invasion: present

[page 2 of 3]
Pathologic Staging (pTNM):

TNM Descriptors: None known

Primary tumor (pT): pT2b

Regional lymph nodes (pN): pN1

Number examined: 31

Number involved: 3

If lymph node(s) involved, specify involved nodal station(s):

ipsilateral peribronchial

Distant metastasis (pM): pMX

Notes:

Totally, seven lymph nodes are fibrotic or with central necrosis, but there is no carcinoma. These lymph nodes are located in the peribronchial, level 7 and lower paratracheal regions.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSF: Bronchial margin:

Negative for malignancy.

Gross Description:

The specimens are received in six formalin filled containers, all labeled with the patient's name

Part A is additionally labeled "right lung (for precision)." The specimen consists of a right lung with dimensions of 21 x 12 x 6.5 cm. The lung has a weight of 400 grams. There are multiple stapled vascular structures present at the hilum. Additionally, there are staple lines within the parenchyma that have a total length of 13 cm. The surgical staple lines are removed and the parenchymal margins are inked blue. The pleural surface of the specimen is gray-purple to tan-white and generally smooth. The pleural surface has been inked black overlying the area of the mass and a portion of the tissue sent for precision diagnostic studies. The specimen is remarkable for a firm tan-white fungating mass within the bronchus of the right upper lobe. Serial sectioning reveals that the mass has overall dimensions of 6 x 5 x 4 cm. The cut surfaces of the mass are firm, tan-white and heterogeneous with areas of necrosis and hemorrhage. The mass appears to fill the majority of the right upper bronchus and erode through the wall. It comes to within 0.1 cm of the pleural surface. The mass comes to within 0.5 cm of the inked parenchymal margin. The remaining uninvolved lung is pink-tan to red-brown and spongy. The bronchial spaces are filled with gray-green mucoid material. Multiple lymph nodes are present adjacent to the hilar structures. These range in greatest dimension from 0.5 to 1.3 cm.

Cassettes are submitted as follows:

A1 vascular margin;

[page 3 of 3]
- A2-3 mass in right upper bronchus;
- A4 mass to nearest parenchymal margin;
- A5-6 remaining parenchymal margin taken en face;
- A7 mass to pleura;
- A8-11 additional representative sections of mass;
- A12 uninvolved lung;
- A13-15 multiple lymph nodes submitted in toto;
- A16 one lymph node bisected.

Part B is additionally labeled "level 7 subcarinal lymph node." The specimen consists of a gray-tan irregular tissue with dimensions of 3.8 x 3 x 1 cm. This may represent a single lymph node or multiple matted lymph nodes. Sectioning reveals multiple tan-white areas of discoloration within the tissue, as well as focal calcification. The specimen is serially sectioned and submitted entirely in cassettes B1-B5 following decalcification.

Part C is additionally labeled "upper paratracheal lymph node." The specimen consists of a portion of yellow-tan fibrofatty tissue with dimensions of 3.3 x 2.3 x 0.6 cm. Multiple probable lymph nodes are identified with greatest dimensions ranging from 0.3 to 0.6 cm. These nodes are submitted in toto in cassette C1.

Part D is additionally labeled "lower paratracheal lymph node." The specimen consists of a portion of yellow-tan lobulated fibrofatty tissue with dimensions of 4.2 x 3.1 x 1.5 cm. Palpation and sectioning reveals multiple probable lymph nodes with greatest dimensions ranging from 0.4 to 3 cm. Sectioning of the largest of these nodes reveals abundant calcification.

Cassettes are submitted as follows:

- D1-2 multiple whole probable lymph nodes;
- D3-5 one lymph node submitted entirely, pending decalcification.

Part E is additionally labeled "level 10 lymph node." The specimen consists of two portions of gray-tan fibrofatty tissue with dimensions of 1.6 x 0.7 x 0.3 cm and 1.5 x 1.2 x 0.5 cm. The smaller tissue is submitted in toto in cassette E1. The larger tissue is bisected and submitted entirely in cassette E2.

Part F is additionally labeled "bronchial margin." The specimen is received fresh for frozen section intraoperative consultation. The specimen consists of a pink-red ring of bronchus that has dimensions of 3.2 x 2.8 x 0.7 cm. This tissue is submitted for frozen section F. The residual tissue from frozen section F is bisected and resubmitted in cassettes F1 and F2.

END OF REPORT

Taken:

Source: NCI Genomic Data Commons file 79972a02-0683-4c71-899b-894859eb3d49 (TCGA-90-7767.A9D672EB-90B2-4A1A-8540-D2D7370498D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).